Somatic mutation profile of tumor specimen TARGET-30-PAUJRW-01A (aliquot TARGET-30-PAUJRW-01A-01D) from TARGET case TARGET-30-PAUJRW, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.6 years (944 days).
Specimen TARGET-30-PAUJRW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e470ec38-edc0-47bf-ab4d-5fd9f410a289.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUJRW-10A (Blood Derived Normal), aliquot TARGET-30-PAUJRW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cc20645-1ec5-4657-aca0-7b9c15e930bf

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HDAC9 | c.647G>T p.R216L | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67769639; called by muse, mutect2
- GPRASP1 | c.2768C>A p.P923Q | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- PTPRH | c.2217G>A p.K739= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1322483078; called by muse, mutect2, varscan2
- REPS2 | c.*314G>T | 3'UTR (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- RLIM | c.*387G>T | 3'UTR (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
